Somatic mutation profile of tumor specimen TCGA-DU-7018-01A (aliquot TCGA-DU-7018-01A-11D-2024-08) from TCGA case TCGA-DU-7018, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 57.5 years (21,019 days).
Specimen TCGA-DU-7018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf43be90-b893-4512-84d3-1af9016642c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7018-10A (Blood Derived Normal), aliquot TCGA-DU-7018-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4da8a7e-56d4-4412-9a86-10ef3f1e991f

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Frame Shift Del 3, Translation Start Site 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 47/96 reads (49%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLRN3 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64098807; called by muse, mutect2
- CPEB4 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.041); catalogued as COSV54173791; called by muse, mutect2, varscan2
- CPS1 | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242767; called by muse, mutect2, varscan2
- DAB2 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs374766869; called by muse, mutect2, varscan2
- EDEM2 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773776079, COSV65713252; called by muse, mutect2, varscan2
- ESX1 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65424757; called by muse, mutect2, varscan2
- FGD6 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59690674; called by muse, mutect2
- GPR83 | c.995G>T p.W332L | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781081403, COSV54719510; called by muse, mutect2, varscan2
- HS3ST6 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV53535595; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1384C>T p.L462F (on ENST00000439118 / NM_001008949.3; = p.L470F on NM_178495.6) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.813); catalogued as COSV63154017; called by muse, mutect2, varscan2
- MYOM2 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50731601; called by muse, mutect2, varscan2
- NOTCH1 | c.6191C>T p.P2064L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53043143; called by muse, mutect2
- PCNX3 | c.3176T>G p.I1059S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV63138478; called by muse, mutect2, varscan2
- PDE8A | c.2414A>G p.H805R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV59638444; called by muse, mutect2, varscan2
- PLCD3 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as COSV59561411; called by muse, mutect2, varscan2
- PSMC3 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV54081679; called by muse, mutect2
- RNF180 | c.687_688del p.H229Qfs*8 | Frame Shift Del (DEL) | VAF 16/125 reads (13%) | catalogued as rs1275399435; called by mutect2, pindel, varscan2
- RUFY4 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs933440305, COSV60248296; called by muse, mutect2, varscan2
- SASH3 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768613358, COSV63555686; called by muse, mutect2, varscan2
- SMARCA4 | c.3702C>G p.F1234L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV60791545, COSV60800759; called by muse, mutect2, varscan2
- SMARCAL1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as CM101359, COSV61921972; called by muse, mutect2
- STAB2 | c.5224-1G>A p.X1742_splice | Splice Site (SNP) | VAF 4/60 reads (7%) | catalogued as COSV66342125; called by muse, mutect2
- VPS13B | c.5219T>C p.V1740A | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV62148331; called by muse, mutect2, varscan2
- ZNF91 | c.2584G>A p.A862T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.975); catalogued as COSV56087641; called by muse, mutect2, varscan2
- CIC | c.436_437del p.S146* | Frame Shift Del (DEL) | VAF 15/29 reads (52%) | called by pindel, varscan2
- MRPL15 | c.323_326del p.G108Vfs*10 | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- APOBEC3B | c.924C>T p.F308= | Silent (SNP) | VAF 37/237 reads (16%) | catalogued as rs144471703; called by muse, mutect2, varscan2
- GPBP1L1 | c.177A>G p.L59= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV51970871; called by muse, mutect2, varscan2
- NKAPL | c.1110A>G p.A370= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV59198398; called by muse, mutect2, varscan2
- OR1A1 | c.225G>A p.S75= | Silent (SNP) | VAF 21/211 reads (10%) | catalogued as rs113780617, COSV58404194; called by muse, mutect2, varscan2
- OTUD5 | c.966C>T p.D322= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as rs782314088, COSV50235908; called by muse, mutect2, varscan2
- PCDHGA11 | c.675C>T p.G225= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs1218675162, COSV53925687; called by muse, mutect2
- PPP1R3A | c.3156T>C p.T1052= | Silent (SNP) | VAF 109/247 reads (44%) | catalogued as COSV52886342; called by muse, mutect2, varscan2
- PRDM14 | c.1155G>A p.P385= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs769530782, COSV52573512; called by muse, mutect2
- PTPRU | c.2679C>A p.G893= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100112463; called by muse, varscan2
- SMYD1 | c.678C>G p.S226= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV101352441, COSV70224535, COSV70225484; called by muse, mutect2, varscan2
- SOAT1 | c.1473T>C p.N491= | Silent (SNP) | VAF 23/234 reads (10%) | catalogued as COSV62655363; called by muse, mutect2
- MIR509-1 | n.14G>T | RNA (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
